Gene-level copy-number profile of tumor specimen TCGA-CV-7104-01A from TCGA case TCGA-CV-7104, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.2 years (22,349 days).
Specimen TCGA-CV-7104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.588a83fb-2b23-4f8a-9718-5d6528ad3e49.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7104-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed5b008c-ff4f-4e8b-b6f5-5b7b76ab39bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,185; copy number 2: 42,294; copy number 3: 2,699; copy number 4: 1,556; copy number 5: 4; copy number 6: 7; copy number 7: 28; copy number 18: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7104-01A-11D-2010-01): tumor purity 0.53, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 85 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:105,546,089–106,060,524, 1 gene, copy number 6 (within-gene range 4–6): ZFPM2-AS1.
- chr8:105,737,280–106,272,902, 6 genes, copy number 6: RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr9:34,702,953–34,774,466, 1 gene, copy number 7 (within-gene range 1–7): AL162231.5.
- chr9:34,723,053–36,014,623, 73 genes, copy number 7–18 (within-gene range 4–18) (broad region; genes not listed).
- chr11:97,657,464–98,131,198, 4 genes, copy number 5: RNA5SP347, LINC02713, AP003730.1, AP001317.1.

Autosomal genes at a single copy (total copy number 1): 10,764. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
